Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8363, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8363-01A (Primary Tumor).

[page 1 of 4]
		Case ID	Gross Description	Microscopic Description

[page 2 of 4]
Diagnosis Details	Comments	Formatted Path Report
		STOMACH TISSUE CHECKLIST Specimen type: Excision of tumor Tumor site: Antrum Tumor size: 7.5 x 6 x 1 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Muscularis propria Lymph nodes: 0/11 positive for metastasis (Regional 0/11) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 4]
	ID	Excision Date

[page 4 of 4]
Laterality

Source: NCI Genomic Data Commons file 98e076c2-f983-474f-84dd-dda47e39e1df (TCGA-BR-8363.A9B7AE6A-69D4-41D3-82F9-7FABDA8BB680.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).